Somatic mutation profile of cancer-model specimen HCM-CSHL-0162-C19-85B (3D Organoid; aliquot HCM-CSHL-0162-C19-85B-01D-A786-36), derived from the primary tumor of HCMI case HCM-CSHL-0162-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.4 years (22,776 days).
Specimen HCM-CSHL-0162-C19-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93170bd8-fd97-4cde-9e23-16534492d5d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0162-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0162-C19-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16540ca4-7abe-4be3-9373-e0161ca09fd9

The open-access MAF lists 152 somatic variants for this specimen: 100 protein-altering or splice-affecting, 32 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 32, Intron 9, Nonsense Mutation 6, 3'UTR 6, Frame Shift Ins 2, 5'UTR 2, Splice Region 2, 3'Flank 1, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 231/231 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACTA1 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 44/595 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs398123562, CM034492; called by muse, mutect2
- ADAMTS16 | c.3451G>A p.V1151M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200745446, COSV57007953; called by muse, mutect2, varscan2
- AMER1 | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 54/584 reads (9%) | catalogued as COSV57664371; called by muse, mutect2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by muse, mutect2, varscan2
- ARHGAP23 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747519450; called by muse, mutect2, varscan2
- ATCAY | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 221/501 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs375699107; called by muse, mutect2, varscan2
- ATP6V0D2 | c.302+1G>A p.X101_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as rs760220576, COSV53413110; called by muse, mutect2, varscan2
- B4GALNT1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs139453491, COSV57541086; called by muse, mutect2, varscan2
- BEGAIN | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 87/135 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1306583469, COSV62068416; called by muse, mutect2, varscan2
- C10orf71 | c.1733C>A p.A578D | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100110708; called by muse, mutect2, varscan2
- CBY2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 128/167 reads (77%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs765472548, COSV60118235; called by muse, mutect2, varscan2
- CHST5 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 69/343 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as rs775382687, COSV60337063; called by muse, mutect2, varscan2
- CNOT3 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs746475797; called by muse, mutect2, varscan2
- COL5A3 | c.4187C>T p.T1396I | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1241146996; called by muse, mutect2
- CPSF3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs757160812, COSV53009954; called by muse, mutect2, varscan2
- CRNN | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs201339909; called by muse, mutect2, varscan2
- DGCR8 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100707762, COSV61225642; called by muse, mutect2, varscan2
- EDNRB | c.337C>T p.R113W (on ENST00000377211 / NM_001201397.1; = p.R23W on NM_000115.5) | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.459); catalogued as rs769618877; called by muse, mutect2, varscan2
- EPHA10 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750207231, COSV57625960; called by muse, mutect2, varscan2
- EZR | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765806455; called by muse, mutect2, varscan2
- FBXO3 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.678); catalogued as rs1371772982, COSV55765156; called by muse, mutect2, varscan2
- FCHSD2 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV60806938; called by muse, mutect2, varscan2
- GREB1 | c.5839C>T p.R1947* | Nonsense Mutation (SNP) | VAF 250/404 reads (62%) | catalogued as rs769237746, COSV52195557; called by muse, mutect2, varscan2
- GRIP2 | c.3412C>T p.R1138W (on ENST00000619221; = p.R1041W on NM_001080423.4) | Missense Mutation (SNP) | VAF 100/190 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); catalogued as rs370347208; called by muse, mutect2, varscan2
- HAS1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 101/189 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99708646; called by muse, mutect2, varscan2
- KRTAP4-16 | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 93/315 reads (30%) | SIFT deleterious (0.01); catalogued as rs746748830; called by muse, mutect2, varscan2
- LAMA4 | c.5297G>T p.R1766M (on ENST00000230538 / NM_001105206.3; = p.R1759M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100037908, COSV57901103; called by muse, mutect2
- LBP | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367547608; called by muse, mutect2, varscan2
- LENEP | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs142005786; called by muse, mutect2, varscan2
- MAU2 | c.1155+3G>A | Splice Region (SNP) | VAF 108/268 reads (40%) | catalogued as rs751386140; called by muse, mutect2, varscan2
- MYO18B | c.6121C>T p.R2041W | Missense Mutation (SNP) | VAF 93/143 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs769227905, COSV59132360; called by muse, mutect2, varscan2
- NELL1 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54299681; called by muse, mutect2, varscan2
- NYX | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100699351; called by muse, mutect2, varscan2
- NYX | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1165773644; called by muse, mutect2, varscan2
- OR6B1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 87/153 reads (57%) | catalogued as rs745433880, COSV68770009; called by muse, mutect2, varscan2
- PCDHA9 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 216/646 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV65323372; called by muse, mutect2, varscan2
- PCDHGB5 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 82/792 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs756009874, COSV53966911; called by muse, mutect2, varscan2
- PDCD1 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 27/173 reads (16%) | catalogued as rs756100729, COSV57690800; called by muse, mutect2, varscan2
- PRAMEF20 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 135/322 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs924762274, COSV57080933; called by muse, mutect2, varscan2
- RASAL3 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 126/258 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs577646736, COSV100640351, COSV59138148; called by muse, mutect2, varscan2
- RBP4 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 92/667 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370579379; called by muse, mutect2, varscan2
- SHANK1 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 142/343 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV53245306; called by muse, mutect2, varscan2
- SIGLEC6 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs776836710; called by muse, mutect2, varscan2
- SIX6 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1365376164, COSV59802308; called by muse, mutect2
- SLC49A4 | c.1111A>G p.S371G | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs771618109; called by muse, mutect2, varscan2
- SRCIN1 | c.1427C>T p.A476V (on ENST00000621492; = p.A442V on NM_025248.3) | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1385907476; called by muse, mutect2, varscan2
- TBX5 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 44/461 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1290011317, COSV59859027; called by muse, mutect2
- TGM2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 101/773 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755189963; called by muse, mutect2, varscan2
- TTN | c.39925G>A p.D13309N (on ENST00000591111; = p.D5885N on NM_003319.4) | Missense Mutation (SNP) | VAF 141/213 reads (66%) | PolyPhen possibly damaging (0.831); catalogued as rs571524382, COSV60064954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBAL3 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 105/189 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs201629154, COSV66814563; called by muse, mutect2, varscan2
- UNC13C | c.4810G>T p.D1604Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99513915; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 249/395 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770075484; called by muse, mutect2, varscan2
- ZNF17 | c.1320G>C p.K440N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV56921915; called by muse, mutect2, varscan2
- ZNF34 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs370110948; called by muse, mutect2, varscan2
- ZNF418 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV101268984; called by muse, mutect2, varscan2
- ZXDC | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 107/226 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs764787409, COSV60446187; called by muse, mutect2, varscan2
- ADAMTS16 | c.2659G>T p.G887W | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADORA2A | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ANK3 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- APC | c.1674_1677del p.N558Kfs*11 | Frame Shift Del (DEL) | VAF 141/144 reads (98%) | called by mutect2, pindel, varscan2
- APEX1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ARNTL | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BSN | c.11182G>T p.A3728S | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- CCDC39 | c.2783G>A p.S928N | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CHST9 | c.1030G>T p.V344L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- COL9A3 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 396/583 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COMMD10 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CR1L | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CRACDL | c.1161G>C p.K387N | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH11 | c.5203T>C p.F1735L | Missense Mutation (SNP) | VAF 94/174 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EZHIP | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- GPX5 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- HELZ | c.1815_1816insTT p.A606Lfs*3 | Frame Shift Ins (INS) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
- IGKV3-15 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 301/1321 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- IGSF10 | c.5567G>A p.W1856* | Nonsense Mutation (SNP) | VAF 22/198 reads (11%) | called by muse, mutect2, varscan2
- KANSL1L | c.2496dup p.Y833Ifs*2 | Frame Shift Ins (INS) | VAF 126/271 reads (46%) | called by mutect2, pindel, varscan2
- KCNJ14 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 89/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM4B | c.3116C>T p.S1039L | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2
- LPIN2 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 210/418 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- LRRTM3 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED16 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NIPAL2 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PKHD1L1 | c.1739C>A p.P580Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PLK4 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 52/52 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN5 | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- QSER1 | c.3261C>A p.N1087K (on ENST00000399302; = p.N1216K on NM_001076786.3) | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.024); called by muse, mutect2
- RXFP2 | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 220/294 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SIGLEC1 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A46 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35A4 | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 81/391 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- SLC6A15 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A11 | c.1255C>A p.R419S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SMR3B | c.32G>T p.W11L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIO | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); called by muse, mutect2
- TUBB6 | c.1021T>G p.F341V | Missense Mutation (SNP) | VAF 116/374 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TUBGCP4 | c.122T>A p.V41D | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- WDR90 | c.1233+7G>A | Splice Region (SNP) | VAF 38/250 reads (15%) | called by muse, mutect2, varscan2
- ZNF782 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN4 | c.773T>C p.I258T | Missense Mutation (SNP) | VAF 105/209 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY3 | c.1797C>T p.S599= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as rs780804787; called by muse, mutect2, varscan2
- ARMC9 | c.1812C>T p.D604= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as rs199727070, COSV100589767, COSV63020146; called by muse, mutect2, varscan2
- ASH1L | c.4581A>T p.R1527= | Silent (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- CDH26 | c.742A>C p.R248= | Silent (SNP) | VAF 64/312 reads (21%) | called by muse, mutect2, varscan2
- CDKN2B | c.312G>A p.A104= | Silent (SNP) | VAF 292/969 reads (30%) | catalogued as rs755236254; called by muse, mutect2, varscan2
- CNTN2 | c.837C>T p.S279= | Silent (SNP) | VAF 31/134 reads (23%) | called by muse, mutect2, varscan2
- ELFN1 | c.387C>T p.R129= | Silent (SNP) | VAF 79/279 reads (28%) | catalogued as rs140278883, COSV70033696, COSV70034978; called by muse, mutect2, varscan2
- FAT4 | c.7323T>C p.D2441= | Silent (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- FCGBP | c.1974C>T p.P658= | Silent (SNP) | VAF 96/188 reads (51%) | catalogued as rs772376965; called by muse, mutect2, varscan2
- FRMD4B | c.3097T>C p.L1033= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2
- GRM1 | c.3207G>A p.P1069= | Silent (SNP) | VAF 157/314 reads (50%) | catalogued as rs1178387181; called by muse, varscan2
- ITGA3 | c.720G>A p.K240= | Silent (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- ITPR2 | c.4437T>C p.V1479= | Silent (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- KCTD13 | c.831A>G p.P277= | Silent (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- KIF2B | c.720G>A p.S240= | Silent (SNP) | VAF 171/283 reads (60%) | catalogued as rs1331727401; called by muse, mutect2, varscan2
- LRRC20 | c.286C>T p.L96= (on ENST00000355790 / NM_207119.3; = p.L46= on NM_018239.4) | Silent (SNP) | VAF 113/354 reads (32%) | catalogued as rs1460455318; called by muse, mutect2, varscan2
- NFATC1 | c.627C>T p.C209= | Silent (SNP) | VAF 37/37 reads (100%) | catalogued as rs541173783; called by muse, mutect2, varscan2
- NLGN4X | c.1299G>A p.P433= | Silent (SNP) | VAF 356/386 reads (92%) | catalogued as rs761743135, COSV52039892; called by muse, mutect2, varscan2
- NUTM1 | c.2340T>C p.D780= | Silent (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- NYAP2 | c.1485C>T p.Y495= | Silent (SNP) | VAF 128/568 reads (23%) | catalogued as rs1473972377, COSV56006709; called by muse, mutect2, varscan2
- PCDHB7 | c.1341C>T p.N447= | Silent (SNP) | VAF 72/781 reads (9%) | catalogued as COSV50760424; called by muse, mutect2
- PPP6R2 | c.2838A>T p.T946= (on ENST00000216061 / NM_001365836.1; = p.T912= on NM_014678.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- PXMP4 | c.345G>A p.V115= | Silent (SNP) | VAF 190/261 reads (73%) | catalogued as rs1332454850; called by muse, mutect2, varscan2
- RBBP5 | c.1140G>C p.V380= | Silent (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- RBFA | c.777C>T p.L259= | Silent (SNP) | VAF 24/30 reads (80%) | catalogued as rs148332133; called by muse, mutect2
- SLC36A2 | c.772C>T p.L258= | Silent (SNP) | VAF 62/368 reads (17%) | called by muse, mutect2, varscan2
- SPDYE4 | c.438C>T p.A146= | Silent (SNP) | VAF 130/130 reads (100%) | catalogued as rs1291643521; called by muse, mutect2, varscan2
- SSUH2 | c.447G>A p.S149= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs144097969; called by muse, mutect2, varscan2
- SYNM | c.3732G>A p.G1244= | Silent (SNP) | VAF 77/276 reads (28%) | called by muse, mutect2, varscan2
- THAP5 | c.348G>A p.K116= (on ENST00000415914 / NM_001130475.3; = p.K74= on NM_182529.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs1458268292; called by muse, mutect2, varscan2
- ZIC1 | c.1062C>T p.H354= | Silent (SNP) | VAF 159/330 reads (48%) | catalogued as COSV51555596, COSV99291725; called by muse, mutect2, varscan2
- ZNF740 | c.564C>T p.D188= | Silent (SNP) | VAF 176/253 reads (70%) | catalogued as rs371041666; called by muse, mutect2, varscan2
- AC092329.3 | c.-211-622G>A | Intron (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- ACTN2 | c.1840-30C>T | Intron (SNP) | VAF 236/514 reads (46%) | called by muse, mutect2, varscan2
- ADGRG6 | c.1069+46T>C | Intron (SNP) | VAF 51/84 reads (61%) | called by muse, mutect2, varscan2
- AL590867.2 | n.95G>A | RNA (SNP) | VAF 78/607 reads (13%) | catalogued as rs370015919; called by muse, mutect2, varscan2
- ALDH3B2 | c.873+14C>T | Intron (SNP) | VAF 84/149 reads (56%) | catalogued as rs748524121; called by muse, mutect2, varscan2
- AOPEP | c.*5-632C>T | Intron (SNP) | VAF 65/175 reads (37%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.*1631A>T | 3'UTR (SNP) | VAF 125/311 reads (40%) | called by muse, mutect2, varscan2
- CCSER1 | c.2011-35281C>G | Intron (SNP) | VAF 38/38 reads (100%) | called by muse, mutect2, varscan2
- CRTC1 | c.*16C>A | 3'UTR (SNP) | VAF 76/388 reads (20%) | called by muse, mutect2, varscan2
- FGFR3 | chr4:1807680 A>G | 3'Flank (SNP) | VAF 52/143 reads (36%) | catalogued as rs1165597238; called by muse, mutect2, varscan2
- FOXP2 | c.1267-1583G>A | Intron (SNP) | VAF 15/81 reads (19%) | catalogued as rs747729448; called by muse, mutect2, varscan2
- MS4A1 | c.-150G>A | 5'UTR (SNP) | VAF 54/54 reads (100%) | catalogued as rs771212311; called by muse, mutect2, varscan2
- NANOS3 | chr19:13874916 C>A | 5'Flank (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- RTL1 | c.-148-4463G>A | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- SDHA | c.*4G>C | 3'UTR (SNP) | VAF 320/712 reads (45%) | called by muse, mutect2, varscan2
- SIRT3 | c.*15C>A | 3'UTR (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- SLC26A4 | c.164+40G>C | Intron (SNP) | VAF 105/216 reads (49%) | called by muse, mutect2, varscan2
- SOHLH2 | c.-13G>A | 5'UTR (SNP) | VAF 42/340 reads (12%) | catalogued as rs766643228, COSV100499534; called by muse, mutect2, varscan2
- ST8SIA2 | c.*19C>A | 3'UTR (SNP) | VAF 85/232 reads (37%) | catalogued as rs1294451539; called by muse, mutect2, varscan2
- TAF10 | c.*1455T>G | 3'UTR (SNP) | VAF 454/746 reads (61%) | called by muse, mutect2, varscan2
